Somatic mutation profile of tumor specimen TCGA-55-6979-01A (aliquot TCGA-55-6979-01A-11D-1945-08) from TCGA case TCGA-55-6979, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 59.6 years (21,780 days).
Specimen TCGA-55-6979-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac319195-ba93-42e2-84bf-14025f4f66d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6979-11A (Solid Tissue Normal), aliquot TCGA-55-6979-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2fe8d87-dd55-42c9-bacf-5e5b6938f96f

The open-access MAF lists 118 somatic variants for this specimen: 94 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 22, Frame Shift Del 4, Nonsense Mutation 2, 3'UTR 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55120643; called by mutect2, varscan2
- ADAM23 | c.1320A>T p.Q440H | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.246); catalogued as rs763169892, COSV52206863; called by muse, mutect2, varscan2
- ADNP2 | c.1726C>G p.L576V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs1343085664, COSV51536534, COSV51540637; called by muse, mutect2, varscan2
- APBA3 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV57463227; called by muse, mutect2, varscan2
- ASAP1 | c.26C>A p.S9Y | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.962); catalogued as COSV100726816; called by muse, varscan2
- CACNA2D4 | c.2081del p.P694Qfs*9 | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | catalogued as COSV54961161; called by mutect2, pindel, varscan2
- CACNG3 | c.89C>A p.T30K | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50075080; called by muse, mutect2, varscan2
- CAD | c.2233C>T p.L745F | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1411504483, COSV53029171; called by muse, mutect2, varscan2
- CBLB | c.973A>G p.R325G | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1289603375, COSV51431438; called by muse, varscan2
- CD6 | c.1377C>G p.I459M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV57840594; called by muse, mutect2
- CLEC16A | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV68499565; called by mutect2, varscan2
- CNKSR2 | c.2894G>C p.R965T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV65279877; called by muse, mutect2
- CNOT10 | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59393531; called by muse, mutect2
- COL10A1 | c.561G>C p.Q187H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.121); catalogued as COSV54573627, COSV54573723; called by mutect2, varscan2
- COL11A1 | c.2009G>C p.G670A | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62186481, COSV62189650; called by muse, mutect2
- CUX2 | c.3487C>A p.L1163M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV55639704; called by mutect2, varscan2
- DHRSX | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348395597, COSV58131454, COSV58136393; called by muse, mutect2, varscan2
- DYRK1A | c.492G>T p.L164F | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV58292700, COSV58295349; called by mutect2, varscan2
- DYRK1B | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as COSV59914208, COSV59914481; called by muse, varscan2
- F13A1 | c.1378C>A p.H460N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as COSV53562472; called by muse, mutect2, varscan2
- FCRL5 | c.2197C>G p.L733V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.667); catalogued as COSV62517337; called by muse, mutect2, varscan2
- FER1L6 | c.3063C>G p.C1021W | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369624500, COSV67548672; called by muse, mutect2
- FLG2 | c.6358A>T p.T2120S | Missense Mutation (SNP) | VAF 74/450 reads (16%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.541); catalogued as COSV66170675; called by muse, mutect2, varscan2
- FNIP2 | c.773C>G p.S258C | Missense Mutation (SNP) | VAF 44/439 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV52442693; called by muse, varscan2
- FOXM1 | c.766C>G p.R256G | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61206733; called by muse, mutect2, varscan2
- GSN | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs779305948, COSV57999401; called by mutect2, varscan2
- GTPBP8 | c.235G>C p.A79P | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.451); catalogued as COSV55606923; called by muse, mutect2, varscan2
- GUCA1A | c.288C>G p.F96L | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV50004741; called by muse, mutect2, varscan2
- HAUS7 | c.243G>T p.W81C | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1556984758, COSV100443975; called by muse, mutect2, varscan2
- HAUS7 | c.242G>T p.W81L | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100443976; called by muse, mutect2, varscan2
- HDLBP | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 26/116 reads (22%) | catalogued as COSV60498760; called by muse, mutect2, varscan2
- HS3ST1 | c.287A>T p.Y96F | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as COSV50024577; called by muse, varscan2
- IGHV3-48 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 41/381 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.483); catalogued as rs375311726; called by muse, mutect2, varscan2
- IRX1 | c.1350G>T p.Q450H | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.498); catalogued as COSV57360892; called by muse, mutect2, varscan2
- KIAA0586 | c.2093A>C p.H698P (on ENST00000619416 / NM_001244190.2; = p.H637P on NM_014749.5) | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV54178982; called by muse, mutect2, varscan2
- KPRP | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV64222278; called by muse, mutect2, varscan2
- KRTAP9-4 | c.11G>T p.C4F | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61898361; called by muse, mutect2, varscan2
- LCT | c.4808C>G p.A1603G | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV51553402; called by muse, mutect2, varscan2
- LCT | c.1990C>A p.P664T | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51553425; called by muse, mutect2, varscan2
- NCOA7 | c.2803G>C p.D935H | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57657562; called by muse, mutect2
- NDN | c.714G>T p.E238D | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.555); catalogued as COSV59361224; called by muse, mutect2, varscan2
- NHP2 | c.177G>C p.Q59H | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.77); catalogued as COSV51071129; called by muse, mutect2
- NISCH | c.4253G>T p.R1418L | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV58740032; called by muse, mutect2, varscan2
- NKRF | c.1844G>T p.R615L | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as rs754192956, COSV58661690, COSV58662253; called by muse, mutect2, varscan2
- OR11G2 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV62132753; called by muse, mutect2, varscan2
- OR2M2 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 17/165 reads (10%) | catalogued as COSV62898871, COSV62898882; called by muse, mutect2
- OR2T2 | c.47C>A p.T16K | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV61618580; called by muse, mutect2
- OR4D6 | c.152G>C p.C51S | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV55660320; called by muse, mutect2, varscan2
- OR5A1 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as rs921174569, COSV100118253, COSV57376316; called by muse, mutect2, varscan2
- OR5A1 | c.71C>A p.P24Q | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV100118258; called by muse, mutect2, varscan2
- OR9G4 | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.533); catalogued as COSV57248564; called by muse, mutect2, varscan2
- PAPOLA | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.383); catalogued as COSV53483261; called by mutect2, varscan2
- PASK | c.3595G>C p.E1199Q | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.223); catalogued as COSV52156182; called by muse, mutect2
- PCDH11X | c.3241A>T p.T1081S | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV100008170; called by muse, mutect2, varscan2
- PCDHGB4 | c.2053G>C p.E685Q | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as COSV53987054; called by muse, mutect2
- PLCB1 | c.502C>A p.R168S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as rs142186851, COSV62059381; called by muse, varscan2
- PLCL2 | c.2173G>T p.G725C (on ENST00000615277 / NM_001144382.2; = p.G599C on NM_015184.5) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67623596; called by mutect2, varscan2
- PNPLA8 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57552268; called by muse, mutect2
- PPP1R10 | c.2299C>A p.H767N | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV64739826; called by muse, mutect2, varscan2
- PRAG1 | c.910G>T p.G304C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV58164137; called by mutect2, varscan2
- PRR11 | c.1060A>T p.S354C | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV51877970; called by muse, mutect2, varscan2
- PSG6 | c.31C>A p.Q11K | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.272); catalogued as COSV51830190, COSV51835363; called by muse, mutect2, varscan2
- PUS7 | c.466A>T p.I156F | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as COSV62677417; called by muse, mutect2, varscan2
- PYCR2 | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV59525182; called by mutect2, varscan2
- ROBO2 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.052); catalogued as COSV59924309; called by muse, mutect2
- SAG | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV68591663; called by muse, mutect2, varscan2
- SCAF11 | c.2958G>C p.K986N | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV65477807; called by muse, mutect2
- SCYL2 | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs568840397, COSV62569693; called by muse, mutect2, varscan2
- SEL1L2 | c.667T>G p.Y223D | Missense Mutation (SNP) | VAF 8/191 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53154746, COSV53157018; called by muse, mutect2
- SENP5 | c.1884+1G>A p.X628_splice | Splice Site (SNP) | VAF 6/64 reads (9%) | catalogued as COSV60208662; called by mutect2, varscan2
- SLC14A2 | c.2186C>T p.S729F | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV54911331; called by muse, mutect2, varscan2
- SLC45A3 | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65655180; called by muse, mutect2, varscan2
- SMARCAL1 | c.1661T>A p.L554H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61922150; called by mutect2, varscan2
- SPTAN1 | c.4452C>G p.I1484M | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV63988435; called by muse, mutect2
- SV2A | c.556G>T p.V186L | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV64965377; called by muse, mutect2, varscan2
- SYT13 | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV50074949; called by mutect2, varscan2
- SYT9 | c.1090C>G p.P364A | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV59621754; called by muse, mutect2
- TACC2 | c.1440G>T p.E480D | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs1168555745, COSV100552559, COSV57763233; called by muse, mutect2, varscan2
- TAOK1 | c.1981G>C p.E661Q | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV55595150; called by muse, mutect2
- TEC | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101202698, COSV67405549; called by muse, mutect2, varscan2
- TENM1 | c.1054G>T p.V352F | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.521); catalogued as rs750097411, COSV64437310; called by muse, mutect2, varscan2
- TMEM79 | c.143G>C p.R48T | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV55295712, COSV55296275; called by muse, mutect2
- TRMU | c.1226A>G p.D409G | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as COSV51990909; called by muse, mutect2
- TTC5 | c.1000G>T p.G334C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51871624; called by muse, varscan2
- TTLL10 | c.888G>C p.E296D (on ENST00000379289 / NM_001130045.2; = p.E223D on NM_153254.3) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as rs1290110939, COSV64960438; called by muse, mutect2
- UNC5D | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as rs765411265, COSV54782007; called by mutect2, varscan2
- USP11 | c.2338C>G p.R780G (on ENST00000218348; = p.R737G on NM_001371072.1) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); catalogued as COSV54474791, COSV54474832; called by muse, mutect2, varscan2
- USP5 | c.2021G>A p.R674H (on ENST00000229268 / NM_001098536.2; = p.R651H on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs782070238, COSV57538848; called by muse, mutect2, varscan2
- ZBTB6 | c.1121A>G p.N374S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65410341; called by muse, mutect2, varscan2
- IGHV7-81 | c.159G>T p.M53I | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHGA4 | c.1438C>A p.P480T | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); called by mutect2, varscan2
- PGM5 | c.1141del p.E381Kfs*67 | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | called by mutect2, pindel, varscan2
- RRM2 | c.656del p.A219Vfs*8 | Frame Shift Del (DEL) | VAF 18/125 reads (14%) | called by mutect2, pindel, varscan2
- TVP23B | c.101_102del p.P34Rfs*41 | Frame Shift Del (DEL) | VAF 38/223 reads (17%) | called by mutect2, pindel, varscan2
- ASAP1 | c.27C>A p.S9= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100726814; called by muse, varscan2
- BACE1 | c.222C>G p.G74= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV57285572; called by muse, mutect2, varscan2
- BEND3 | c.231G>A p.L77= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100944536; called by mutect2, varscan2
- CAPZA3 | c.899A>G p.*300= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1382051915, COSV99855839; called by muse, mutect2, varscan2
- CRYBG1 | c.3876G>T p.P1292= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs199971648, COSV64813853; called by muse, mutect2, varscan2
- CTCFL | c.1317G>C p.R439= | Silent (SNP) | VAF 18/246 reads (7%) | catalogued as COSV54776692; called by muse, mutect2
- DNAH17 | c.165G>T p.T55= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs373068644, COSV101101413; called by muse, mutect2, varscan2
- FOXRED2 | c.1878G>C p.V626= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as COSV53400835; called by muse, mutect2
- FSTL1 | c.102G>T p.V34= | Silent (SNP) | VAF 9/135 reads (7%) | catalogued as COSV55235013; called by muse, mutect2
- IGLV2-8 | c.81C>T p.P27= | Silent (SNP) | VAF 25/244 reads (10%) | called by muse, mutect2, varscan2
- ITCH | c.786C>T p.P262= (on ENST00000262650 / NM_001257137.3; = p.P221= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/114 reads (8%) | catalogued as COSV52934297; called by muse, mutect2
- KCNAB1 | c.405C>G p.L135= (on ENST00000490337 / NM_172160.3; = p.L124= on NM_003471.3) | Silent (SNP) | VAF 17/135 reads (13%) | catalogued as COSV56749391; called by muse, mutect2, varscan2
- LRRC41 | c.1839G>T p.S613= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as COSV58441017; called by muse, mutect2, varscan2
- NTAQ1 | c.156T>G p.A52= | Silent (SNP) | VAF 18/380 reads (5%) | catalogued as COSV54875346; called by muse, mutect2
- OBSCN | c.6885G>T p.P2295= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs746321468, COSV52798618; called by muse, mutect2, varscan2
- OXCT1 | c.99C>T p.S33= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs182901792, COSV52173724; called by mutect2, varscan2
- PEAR1 | c.24C>A p.L8= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV52771789, COSV52774419; called by mutect2, varscan2
- PKD1L1 | c.4491G>T p.G1497= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV56971344; called by muse, mutect2, varscan2
- REPS1 | c.1251C>T p.S417= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV57812379; called by mutect2, varscan2
- SIPA1L1 | c.846C>G p.L282= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV62171876; called by muse, mutect2
- SPEN | c.3675C>T p.S1225= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV65364810; called by mutect2, varscan2
- TMPRSS9 | c.696G>A p.R232= (on ENST00000648592; = p.R198= on NM_182973.2) | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV60229474; called by muse, mutect2, varscan2
- CNNM3 | c.*1C>G | 3'UTR (SNP) | VAF 12/84 reads (14%) | catalogued as COSV100562582; called by muse, mutect2, varscan2
- TTN | c.10360+4264G>T | Intron (SNP) | VAF 6/52 reads (12%) | catalogued as COSV60189553; called by mutect2, varscan2
